Somatic mutation profile of tumor specimen TCGA-CV-7414-01A (aliquot TCGA-CV-7414-01A-11D-2078-08) from TCGA case TCGA-CV-7414, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 78.3 years (28,603 days).
Specimen TCGA-CV-7414-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f42701a0-a2a4-4659-85bf-7a77ec39bcf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7414-10A (Blood Derived Normal), aliquot TCGA-CV-7414-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6aef1bd-b45d-4959-bfe5-2ccb067e23a0

The open-access MAF lists 287 somatic variants for this specimen: 208 protein-altering or splice-affecting, 74 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 186, Silent 74, Nonsense Mutation 16, Splice Site 5, 3'Flank 2, Frame Shift Ins 1, Intron 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 28/35 reads (80%) | hotspot (GDC flag); catalogued as rs1057519852, COSV58682976, COSV58690849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC4A11 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121909388, CM063151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 28/37 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL5 | c.209C>G p.P70R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV100389275; called by muse, mutect2, varscan2
- ADH4 | c.844-1G>C p.X282_splice | Splice Site (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99644077; called by muse, mutect2
- AGBL1 | c.327G>C p.R109S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101407816, COSV101408289; called by muse, mutect2, varscan2
- AHNAK | c.4666G>C p.E1556Q | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV99950120; called by muse, mutect2, varscan2
- AKAP6 | c.361A>G p.I121V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs1386904426, COSV99805217; called by muse, mutect2, varscan2
- AQP11 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100547413; called by muse, mutect2, varscan2
- ARHGAP26 | c.1672G>C p.E558Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV99191597; called by muse, mutect2, varscan2
- ARHGAP30 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100920558; called by muse, mutect2, varscan2
- ARHGAP5 | c.740A>G p.D247G | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100565745; called by muse, mutect2, varscan2
- ASH2L | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.263); catalogued as COSV99167055; called by muse, mutect2
- ATAD1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100058502; called by muse, mutect2, varscan2
- ATAD5 | c.4720G>C p.D1574H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1038921475, COSV100430289, COSV58971940; called by muse, mutect2, varscan2
- ATAD5 | c.5434G>C p.E1812Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100035326; called by muse, mutect2, varscan2
- ATP6V1E1 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99494495; called by muse, mutect2, varscan2
- BPIFA1 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 112/295 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.029); catalogued as rs1275490700, COSV100845668; called by muse, mutect2, varscan2
- BRPF3 | c.3254G>C p.R1085P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100326263, COSV60206326; called by muse, mutect2, varscan2
- BSN | c.10064C>G p.S3355* | Nonsense Mutation (SNP) | VAF 3/36 reads (8%) | catalogued as COSV99610113; called by muse, mutect2
- CA6 | c.878T>G p.L293R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV101077731; called by muse, mutect2, varscan2
- CACNA2D1 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV100667599; called by muse, mutect2, varscan2
- CAPN2 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99689360; called by muse, mutect2
- CCDC90B | c.427-1G>C p.X143_splice | Splice Site (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99475458; called by muse, varscan2
- CD40 | c.730G>C p.G244R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV100953883; called by muse, mutect2, varscan2
- CDH11 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.852); catalogued as rs777888128, COSV51758031, COSV51781763; called by muse, mutect2, varscan2
- CDH23 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | catalogued as COSV99824417; called by muse, mutect2
- CDH7 | c.673C>A p.Q225K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as COSV100542832; called by muse, mutect2, varscan2
- CDK18 | c.1334C>T p.S445L (on ENST00000506784 / NM_212503.3; = p.S415L on NM_002596.4) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV100774117; called by muse, mutect2
- CFAP69 | c.1873T>A p.F625I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.194); catalogued as rs762305642, COSV60189891; called by muse, varscan2
- CHD7 | c.8519C>G p.T2840S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV101418553, COSV71114721; called by mutect2, varscan2
- COG3 | c.1931-2A>G p.X644_splice | Splice Site (SNP) | VAF 7/71 reads (10%) | catalogued as COSV100596791; called by muse, mutect2
- COG7 | c.1007T>A p.L336Q | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100207895; called by muse, mutect2, varscan2
- COL11A1 | c.3096A>T p.R1032S | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99058249; called by muse, mutect2, varscan2
- COL27A1 | c.3100A>C p.M1034L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100621397; called by muse, mutect2, varscan2
- CORO1A | c.1011C>G p.F337L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV99532256; called by muse, mutect2
- CRADD | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.185); catalogued as COSV100257922; called by muse, mutect2, varscan2
- CROCC | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.324); catalogued as rs200142599; called by muse, mutect2
- CSF2RB | c.2341A>T p.R781W | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1268684586, COSV53260038; called by muse, mutect2, varscan2
- CSH2 | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs568921116, COSV100400369; called by muse, mutect2, varscan2
- CSRP3 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs397516851, COSV99788451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTAGE1 | c.2174C>A p.P725Q | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101194721; called by muse, mutect2, varscan2
- CXorf21 | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 36/45 reads (80%) | catalogued as COSV100973378, COSV100973382; called by muse, mutect2, varscan2
- CYP2E1 | c.797C>G p.T266S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV99429297; called by muse, mutect2, varscan2
- CYP4A11 | c.227A>C p.Q76P | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV100152695; called by muse, mutect2, varscan2
- DCP1B | c.1403C>G p.S468C | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs781036714, COSV99768024; called by muse, mutect2
- DHPS | c.668G>A p.W223* | Nonsense Mutation (SNP) | VAF 81/193 reads (42%) | catalogued as COSV99269790; called by muse, mutect2, varscan2
- DHX9 | c.2044C>G p.Q682E | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV100841557; called by muse, mutect2
- DIS3L | c.538G>T p.V180L (on ENST00000319212 / NM_001143688.3; = p.V97L on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV100055687; called by muse, varscan2
- DLL1 | c.1930G>A p.V644M | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs187849210, COSV64538270; called by muse, mutect2, varscan2
- DNAH11 | c.6479T>G p.L2160R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100181379; called by muse, mutect2, varscan2
- DNAH5 | c.2825C>T p.T942M | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1332078256, COSV99455366; called by muse, mutect2, varscan2
- DNAH6 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.286); catalogued as rs145235960; called by muse, mutect2, varscan2
- DNAJA3 | c.603C>G p.F201L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs781398518, COSV52164159, COSV99277137; called by muse, mutect2, varscan2
- DOCK1 | c.4792G>C p.E1598Q | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV99733539; called by muse, mutect2, varscan2
- DOP1A | c.6390-2A>T p.X2130_splice | Splice Site (SNP) | VAF 24/65 reads (37%) | catalogued as COSV99383118; called by muse, mutect2, varscan2
- DPPA2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV72118065; called by muse, mutect2
- EIF2S2 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV66621631, COSV66621640; called by muse, mutect2, varscan2
- ELOVL1 | c.532A>G p.M178V | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100196711; called by muse, mutect2, varscan2
- ELOVL5 | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100439987; called by muse, mutect2, varscan2
- ENAM | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as rs769115693, COSV68535985, COSV68537216; called by muse, mutect2, varscan2
- ENPP7 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100093244, COSV100093791; called by muse, mutect2, varscan2
- FAM133B | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV101300235; called by muse, mutect2, varscan2
- FAM9B | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100511139; called by muse, mutect2, varscan2
- FBXL20 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 17/132 reads (13%) | catalogued as COSV52897487; called by muse, mutect2, varscan2
- FBXO38 | c.2458C>G p.L820V | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV99694114; called by muse, mutect2, varscan2
- FCGBP | c.11239G>A p.E3747K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.803); catalogued as rs200275847; called by muse, mutect2, varscan2
- FOXG1 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.122); catalogued as COSV57395888; called by muse, mutect2, varscan2
- FRMD6 | c.58A>G p.I20V | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100656409; called by muse, mutect2, varscan2
- FRYL | c.2451C>G p.H817Q | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV99978483; called by muse, mutect2, varscan2
- GKN1 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 4/66 reads (6%) | catalogued as COSV100933624; called by muse, mutect2
- GOLGA2 | c.1706G>C p.G569A | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100360463; called by muse, mutect2
- GPR137B | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as rs147708340, COSV99053743; called by muse, mutect2, varscan2
- GREB1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1471934505, COSV52186592; called by muse, mutect2
- GRIN2B | c.1686G>A p.M562I | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV101663222; called by muse, mutect2
- GRM1 | c.1318G>C p.D440H | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV51274803, COSV99269628; called by muse, mutect2
- GTF2IRD1 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as COSV99735781; called by muse, mutect2
- H4C3 | c.203G>C p.R68P | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs778987751, COSV58090178; called by muse, mutect2, varscan2
- HARBI1 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs976983246, COSV58705878; called by muse, mutect2, varscan2
- HNRNPF | c.824G>A p.R275K | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV100563367; called by muse, mutect2, varscan2
- HSP90AB1 | c.52C>G p.Q18E | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as COSV62334504, COSV62336891; called by muse, mutect2, varscan2
- IGHM | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as rs782090515; called by muse, mutect2, varscan2
- ILKAP | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as rs1231947882, COSV54519415, COSV99611224; called by muse, mutect2, varscan2
- ITSN2 | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as COSV100744279; called by muse, mutect2, varscan2
- JAKMIP1 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51523568, COSV51535873; called by muse, mutect2
- KAT2B | c.1911C>G p.I637M | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99770006; called by muse, mutect2, varscan2
- KIAA1109 | c.4037C>G p.S1346C | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99192061; called by muse, mutect2
- KIF6 | c.2397C>G p.I799M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.295); catalogued as COSV54692539, COSV99761201; called by muse, mutect2, varscan2
- KLF10 | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99574981; called by muse, mutect2, varscan2
- KMT5B | c.605G>C p.R202T | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100070098; called by muse, mutect2, varscan2
- KRT26 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.281); catalogued as COSV100156639, COSV59415340; called by muse, mutect2
- KSR2 | c.1751C>T p.T584M | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as rs374020752; called by muse, mutect2, varscan2
- LAMA4 | c.5327-1G>C p.X1776_splice (on ENST00000230538 / NM_001105206.3; = p.X1769_splice on NM_002290.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/38 reads (47%) | catalogued as COSV100039744; called by muse, mutect2, varscan2
- LARP4B | c.749A>T p.E250V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100295784; called by muse, varscan2
- LBP | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.098); catalogued as COSV54141535; called by muse, mutect2, varscan2
- LCP1 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.864); catalogued as rs762754615, COSV100550120; called by muse, mutect2, varscan2
- LRRC18 | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV53285898, COSV99631233; called by muse, mutect2, varscan2
- MAGEL2 | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as rs761568970, COSV100045670, COSV58568250; called by muse, mutect2, varscan2
- MAP3K20 | c.2005G>C p.E669Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.517); catalogued as COSV100919667, COSV64380592; called by muse, mutect2, varscan2
- MAP3K4 | c.469C>G p.R157G | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100815102, COSV100815745; called by muse, mutect2
- MAPK10 | c.223G>A p.V75I (on ENST00000359221 / NM_001351625.2; = p.V113I on NM_002753.5) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.073); catalogued as rs1561780045, COSV100175644; called by muse, mutect2, varscan2
- MCF2L2 | c.2722C>G p.L908V | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100194198; called by muse, mutect2
- MED1 | c.3446C>T p.S1149F | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV100328232; called by muse, mutect2, varscan2
- MED1 | c.2585G>A p.G862E | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as rs768722798, COSV100328234; called by muse, mutect2, varscan2
- MRS2 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.355); catalogued as COSV99219202; called by muse, mutect2, varscan2
- MSANTD4 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV100108684; called by muse, mutect2
- MSL2 | c.1428C>G p.C476W | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV99388427; called by muse, mutect2, varscan2
- MTDH | c.1653G>C p.K551N | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100292851; called by muse, mutect2, varscan2
- MTHFS | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV99358384; called by muse, mutect2, varscan2
- MUC13 | c.71C>G p.S24* | Nonsense Mutation (SNP) | VAF 6/132 reads (5%) | catalogued as COSV100222532; called by muse, mutect2
- MUC16 | c.6733G>A p.E2245K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs765623312, COSV101202109; called by muse, mutect2, varscan2
- MUC3A | c.8875G>C p.D2959H | Missense Mutation (SNP) | VAF 10/342 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV100115601; called by muse, mutect2
- MYO15A | c.1593C>G p.F531L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV99234842; called by muse, mutect2, varscan2
- MYO1C | c.2263C>A p.L755I (on ENST00000648651 / NM_001080779.2; = p.L720I on NM_033375.5) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as COSV100704597; called by muse, mutect2, varscan2
- NAGPA | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 8/106 reads (8%) | PolyPhen benign (0.026); catalogued as COSV100393131; called by muse, mutect2
- NID2 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV99357425; called by muse, mutect2
- NRDE2 | c.188C>G p.S63* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100583702; called by muse, mutect2, varscan2
- NSMAF | c.1495A>G p.S499G | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV99233606; called by muse, mutect2, varscan2
- NSUN7 | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs1166422360, COSV100349843; called by muse, mutect2, varscan2
- NUP188 | c.1779C>G p.I593M | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV101001534; called by muse, mutect2, varscan2
- OR10G8 | c.659T>C p.I220T | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs1048987326, COSV101461890; called by muse, mutect2, varscan2
- OR13A1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs768334723, COSV65572402; called by muse, mutect2, varscan2
- PCARE | c.2183G>C p.R728T | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100527996; called by muse, mutect2
- PCDHB6 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs781983350, COSV99173251; called by muse, mutect2
- PCLO | c.3784C>T p.H1262Y | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs1562888708, COSV100439216; called by muse, mutect2, varscan2
- PDSS1 | c.1151G>A p.C384Y | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV100698142; called by muse, mutect2, varscan2
- PLB1 | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV59832525; called by muse, mutect2
- PLOD3 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs772269466, COSV56183874; called by muse, mutect2, varscan2
- PLOD3 | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV56186027, COSV99778354; called by muse, mutect2, varscan2
- PNLDC1 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99277972; called by muse, mutect2
- POTEE | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV100389252; called by mutect2, varscan2
- PRKCA | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.158); catalogued as rs987622627, COSV52593918, COSV52594468; called by muse, mutect2, varscan2
- PRKCI | c.1319G>C p.G440A | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99856229; called by muse, mutect2, varscan2
- PRKD3 | c.380C>G p.S127* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | catalogued as COSV52212992, COSV99306896; called by muse, mutect2
- PTGDR | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770154151, COSV60093408; called by muse, mutect2, varscan2
- PTPRJ | c.2882C>G p.S961* | Nonsense Mutation (SNP) | VAF 10/125 reads (8%) | catalogued as COSV101395807; called by muse, mutect2
- PTX3 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV99904741; called by muse, mutect2, varscan2
- PXDNL | c.3372G>C p.Q1124H | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV100687027; called by muse, mutect2, varscan2
- QRICH2 | c.3154G>C p.D1052H | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99429844; called by muse, mutect2, varscan2
- RANBP3L | c.470C>A p.T157K | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as COSV99684130; called by muse, mutect2, varscan2
- RASA1 | c.2086A>G p.I696V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99171353; called by muse, mutect2, varscan2
- RBPJL | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV100643569; called by muse, mutect2, varscan2
- RDH11 | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.682); catalogued as COSV101191559; called by muse, mutect2
- RDH12 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV99961957; called by muse, mutect2
- RGS6 | c.583C>G p.Q195E | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100667208; called by muse, mutect2
- RNASE10 | c.166A>T p.T56S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV100116230; called by muse, mutect2, varscan2
- RTN1 | c.2005C>T p.Q669* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99957128; called by muse, mutect2, varscan2
- RYBP | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 16/35 reads (46%) | catalogued as COSV101523327; called by muse, mutect2
- SCN11A | c.5092G>C p.D1698H | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as rs931547722, COSV100182880; called by muse, mutect2
- SETBP1 | c.3565C>T p.R1189W | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1380272330, COSV56327337, COSV56329995; called by muse, mutect2
- SETX | c.2186G>C p.R729T | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV99811253; called by muse, mutect2
- SF3A1 | c.2284A>G p.I762V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as COSV99305494; called by muse, mutect2, varscan2
- SI | c.532A>C p.K178Q | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100017513; called by muse, mutect2, varscan2
- SIPA1L2 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1177262652, COSV53397330; called by muse, mutect2
- SLC10A6 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761317022, COSV99907423; called by muse, mutect2, varscan2
- SLC25A22 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs202242484, COSV100204341; called by muse, mutect2, varscan2
- SLC26A9 | c.1727G>A p.R576K | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs566271291, COSV100536931; called by muse, mutect2, varscan2
- SLC27A2 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99983152; called by muse, mutect2
- SMG1 | c.1793A>T p.K598M | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV101246977; called by muse, mutect2, varscan2
- SNTG2 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100425316; called by muse, mutect2, varscan2
- SORBS2 | c.644A>G p.Y215C (on ENST00000284776 / NM_021069.5; = p.Y261C on NM_003603.6) | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99513187; called by muse, mutect2, varscan2
- SORCS2 | c.1902G>C p.W634C | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100214268; called by muse, mutect2, varscan2
- SPDYE3 | c.1630G>C p.D544H | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781753979, COSV100193897, COSV60107732; called by muse, mutect2, varscan2
- SPTLC2 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99378030; called by muse, mutect2, varscan2
- SYT8 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV99425654; called by muse, mutect2, varscan2
- SYT9 | c.982C>G p.L328V | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1345681759, COSV100609473, COSV59620410; called by muse, mutect2, varscan2
- TDP1 | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100188181; called by muse, mutect2, varscan2
- TEX264 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as COSV100392794; called by muse, mutect2
- TLK2 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100409662; called by muse, mutect2, varscan2
- TMEM177 | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1014623691, COSV99733763; called by muse, mutect2, varscan2
- TMPRSS3 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.295); catalogued as rs777595673, CM122452, COSV99368817; called by muse, mutect2, varscan2
- TOR1AIP2 | c.1301C>G p.S434C | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100857564, COSV62625414; called by muse, mutect2
- TP53BP1 | c.4831C>G p.L1611V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1020437356, COSV99781718; called by muse, mutect2
- TRAK2 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs146913241; called by muse, mutect2, varscan2
- TRAPPC8 | c.2816A>G p.N939S | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1342549349, COSV99350805; called by muse, mutect2, varscan2
- TRIM16L | c.654G>T p.E218D | Missense Mutation (SNP) | VAF 44/52 reads (85%) | SIFT tolerated (0.31); PolyPhen benign (0.058); catalogued as COSV101192601; called by muse, mutect2, varscan2
- TRIM36 | c.1485C>G p.I495M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as rs777817315, COSV99142863; called by mutect2, varscan2
- TRPM7 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100540458; called by muse, mutect2, varscan2
- TSPYL4 | c.944A>G p.Y315C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100127369; called by muse, mutect2, varscan2
- TSSK6 | c.226T>C p.F76L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV99389336; called by muse, varscan2
- TTN | c.87988G>C p.D29330H (on ENST00000591111; = p.D21906H on NM_003319.4) | Missense Mutation (SNP) | VAF 5/85 reads (6%) | PolyPhen possibly damaging (0.824); catalogued as COSV100634599, COSV59888789; called by muse, mutect2
- UBC | c.351G>C p.Q117H | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100299173; called by muse, mutect2, varscan2
- USP31 | c.994C>G p.H332D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV54850897, COSV99566076; called by muse, mutect2, varscan2
- USPL1 | c.3178G>C p.D1060H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55000626, COSV99687660; called by muse, mutect2
- VIRMA | c.262G>C p.G88R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99889741; called by muse, mutect2, varscan2
- VPS13C | c.3016C>T p.Q1006* (on ENST00000644861 / NM_020821.3; = p.Q963* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV99830602; called by muse, mutect2, varscan2
- VPS35L | c.2208G>T p.Q736H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as rs1168599151, COSV99221928; called by muse, mutect2, varscan2
- WASHC2C | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.519); catalogued as rs782597041, COSV100314141; called by muse, mutect2, varscan2
- WNK4 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); catalogued as COSV99519600; called by muse, mutect2, varscan2
- WNT7B | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100255384; called by muse, mutect2, varscan2
- XCR1 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as rs184118987; called by muse, mutect2, varscan2
- XIRP2 | c.8706G>T p.E2902D (on ENST00000628543; = p.E3077D on NM_152381.6) | Missense Mutation (SNP) | VAF 58/76 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as COSV99748723; called by muse, mutect2, varscan2
- YRDC | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.029); catalogued as rs751669677, COSV100888721; called by muse, mutect2
- ZBTB1 | c.46A>T p.N16Y | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.924); catalogued as COSV100704261; called by muse, mutect2, varscan2
- ZC3H3 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 70/120 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs185805345; called by muse, mutect2, varscan2
- ZNF217 | c.1133C>A p.S378Y | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV100184975; called by muse, mutect2
- ZNF226 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.368); catalogued as rs1045613286, COSV100335288; called by muse, mutect2, varscan2
- ZNF335 | c.3910G>C p.D1304H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100533506; called by muse, mutect2, varscan2
- ZNF347 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100498488; called by muse, mutect2, varscan2
- ZNF423 | c.3632G>A p.C1211Y (on ENST00000563137 / NM_001379286.1; = p.C1203Y on NM_015069.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99284226; called by muse, mutect2, varscan2
- ZNF536 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as rs866808463, COSV62821917; called by muse, mutect2, varscan2
- ZNF699 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as COSV100427103; called by muse, mutect2, varscan2
- ZNF750 | c.906C>G p.Y302* | Nonsense Mutation (SNP) | VAF 131/165 reads (79%) | catalogued as COSV53958592, COSV53958606, COSV53960261, COSV53961789; called by muse, mutect2, varscan2
- ZNF91 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100323590; called by muse, mutect2, varscan2
- FAT1 | c.8474dup p.S2826Kfs*2 | Frame Shift Ins (INS) | VAF 25/56 reads (45%) | called by mutect2, pindel, varscan2
- IGKV3D-7 | c.130C>G p.L44V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- POLR2A | c.1844G>A p.S615N | Missense Mutation (SNP) | VAF 107/116 reads (92%) | SIFT tolerated (0.51); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SPATA31A1 | c.3076C>G p.Q1026E | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- AFF3 | c.1167C>T p.L389= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100420330; called by muse, mutect2
- APC2 | c.1830C>T p.L610= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs375055768; called by muse, mutect2, varscan2
- ARFGEF2 | c.4351T>C p.L1451= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV100904544; called by muse, mutect2, varscan2
- ATP11A | c.1029C>G p.L343= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs1286160367, COSV52117418; called by muse, mutect2, varscan2
- BAZ2B | c.5646G>A p.R1882= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as COSV100601135; called by muse, mutect2, varscan2
- C11orf24 | c.942C>T p.I314= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100422771; called by muse, mutect2, varscan2
- C3orf20 | c.2145C>T p.I715= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99514699; called by muse, mutect2, varscan2
- CATSPER1 | c.1584G>C p.L528= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV100376327; called by muse, mutect2, varscan2
- CCDC33 | c.120C>T p.T40= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs753882238, COSV100351973; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4857C>G p.L1619= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs774635195, COSV62571899; called by muse, mutect2, varscan2
- CEBPD | c.258C>T p.F86= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1235739138, COSV99856319; called by muse, mutect2
- CHD6 | c.4659C>G p.L1553= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100951398; called by muse, mutect2, varscan2
- CLSTN1 | c.2187G>C p.L729= (on ENST00000377298 / NM_001009566.3; = p.L719= on NM_014944.4) | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100790812; called by muse, mutect2, varscan2
- COLEC12 | c.774G>A p.L258= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV101232209; called by muse, mutect2, varscan2
- COPB2 | c.735C>T p.I245= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as rs1159098425, COSV100300960; called by muse, mutect2, varscan2
- CSMD3 | c.969C>T p.L323= | Silent (SNP) | VAF 6/146 reads (4%) | catalogued as COSV99851148; called by muse, mutect2
- CTDP1 | c.2874C>T p.N958= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs376904820; called by muse, mutect2, varscan2
- DNAH2 | c.12657C>G p.V4219= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV101209648; called by muse, mutect2, varscan2
- DNTT | c.114C>T p.F38= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100960800; called by muse, mutect2, varscan2
- DSP | c.1533C>T p.I511= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV101131871; called by muse, mutect2, varscan2
- EIF4A2 | c.840C>G p.L280= | Silent (SNP) | VAF 29/178 reads (16%) | catalogued as COSV99961417; called by muse, mutect2, varscan2
- ETV1 | c.102C>T p.F34= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV54138605, COSV99624789; called by muse, mutect2
- EXOC8 | c.72G>A p.A24= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99150185; called by muse, mutect2, varscan2
- FCRL3 | c.897G>C p.L299= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV100943613; called by muse, mutect2
- FOXD4L1 | c.999C>G p.V333= | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as COSV99380901; called by muse, mutect2
- GNAQ | c.174G>A p.Q58= | Silent (SNP) | VAF 73/161 reads (45%) | catalogued as COSV54124546, COSV99682177; called by muse, mutect2, varscan2
- GPD1 | c.420C>T p.L140= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs748557046, COSV99993917; ClinVar: likely benign; called by muse, mutect2, varscan2
- HELZ | c.3594C>G p.V1198= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100699119; called by muse, mutect2
- HSPA4 | c.1539T>C p.D513= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100507934; called by muse, mutect2, varscan2
- KLKB1 | c.1179A>G p.G393= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as COSV99250547; called by muse, mutect2, varscan2
- KRTAP27-1 | c.87C>A p.T29= | Silent (SNP) | VAF 46/153 reads (30%) | catalogued as COSV101239796; called by muse, mutect2, varscan2
- LRRC49 | c.1566C>T p.F522= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV53014052, COSV99538356; called by muse, mutect2, varscan2
- MAN2B1 | c.180G>A p.P60= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1043541354, COSV54418846, COSV54419597; called by muse, mutect2, varscan2
- MAN2B2 | c.1740G>A p.L580= | Silent (SNP) | VAF 41/49 reads (84%) | catalogued as COSV99578258; called by muse, mutect2, varscan2
- MUC17 | c.12015G>A p.V4005= | Silent (SNP) | VAF 12/359 reads (3%) | catalogued as COSV60300364; called by muse, mutect2
- MUC17 | c.12246G>A p.T4082= | Silent (SNP) | VAF 38/337 reads (11%) | catalogued as rs201108444, COSV100072640; called by muse, mutect2, varscan2
- MYO1A | c.2157G>A p.L719= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as rs758170198, COSV100271336; called by muse, mutect2, varscan2
- MYO5C | c.3507G>A p.L1169= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV99955790; called by muse, mutect2, varscan2
- NEXMIF | c.183C>T p.P61= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs779975139, CD136961, COSV99282204; called by muse, mutect2
- NKX2-2 | c.36C>T p.V12= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV65819422; called by muse, mutect2, varscan2
- NPAP1 | c.2310T>A p.P770= | Silent (SNP) | VAF 61/183 reads (33%) | catalogued as COSV100276356; called by muse, mutect2, varscan2
- NRIP3 | c.528C>T p.G176= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV100487289; called by muse, mutect2, varscan2
- NSD3 | c.2073G>A p.S691= | Silent (SNP) | VAF 33/346 reads (10%) | catalogued as rs767903707, COSV57620560; called by muse, mutect2
- NUP93 | c.2343C>T p.R781= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as rs1267768360, COSV57429876; called by muse, mutect2, varscan2
- OR4S2 | c.828C>T p.I276= | Silent (SNP) | VAF 8/190 reads (4%) | catalogued as COSV56747195; called by muse, mutect2
- OR6F1 | c.819T>G p.A273= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as COSV100129512; called by muse, mutect2, varscan2
- PABPC1 | c.75G>C p.A25= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100589938, COSV59406678; called by muse, mutect2, varscan2
- PGGHG | c.2190C>G p.L730= | Silent (SNP) | VAF 12/219 reads (5%) | catalogued as rs982293030, COSV101164768; called by muse, mutect2
- POLR1A | c.1485C>T p.S495= | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as rs747361250, COSV99808608; called by muse, mutect2, varscan2
- PRAMEF18 | c.441G>A p.L147= | Silent (SNP) | VAF 118/515 reads (23%) | called by muse, mutect2, varscan2
- RALGAPA1 | c.4392T>C p.F1464= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs1172639113, COSV99356500; called by muse, mutect2, varscan2
- REST | c.333G>C p.L111= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV100471423; called by muse, mutect2, varscan2
- RNF213 | c.9768G>A p.S3256= | Silent (SNP) | VAF 37/44 reads (84%) | catalogued as rs556455090, COSV100301696; called by muse, mutect2, varscan2
- SHMT1 | c.873T>G p.L291= | Silent (SNP) | VAF 107/201 reads (53%) | catalogued as COSV100363714; called by muse, mutect2, varscan2
- SIPA1L1 | c.2784T>C p.S928= | Silent (SNP) | VAF 54/92 reads (59%) | catalogued as COSV100666158; called by muse, mutect2, varscan2
- SLC2A5 | c.1458G>A p.P486= | Silent (SNP) | VAF 55/139 reads (40%) | catalogued as rs750455456, COSV66236540; called by muse, mutect2, varscan2
- SLC38A2 | c.507G>A p.V169= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV99874173; called by muse, mutect2, varscan2
- SLC39A12 | c.1147C>T p.L383= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV101070197; called by muse, mutect2, varscan2
- SLC6A1 | c.1350T>C p.F450= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as COSV99823326; called by muse, mutect2, varscan2
- SLX4 | c.708G>A p.A236= | Silent (SNP) | VAF 70/200 reads (35%) | catalogued as rs765742613, COSV53567942; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SPAG9 | c.3303C>G p.G1101= (on ENST00000262013 / NM_001130528.3; = p.G1087= on NM_003971.6) | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as COSV100006198; called by muse, mutect2, varscan2
- SRRM4 | c.642G>A p.G214= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV99939639; called by muse, mutect2
- TARBP2 | c.1083C>T p.I361= (on ENST00000266987 / NM_134323.2; = p.I340= on NM_004178.4) | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99908669; called by muse, mutect2, varscan2
- TAS2R46 | c.378G>A p.K126= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV67854660; called by muse, varscan2
- TLN2 | c.3147G>C p.P1049= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100170320; called by muse, mutect2, varscan2
- TNC | c.5784C>G p.V1928= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV100406445; called by muse, mutect2
- U2AF2 | c.12C>T p.F4= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs768925053, COSV58274301; called by muse, mutect2, varscan2
- VPS13B | c.9927A>G p.L3309= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV100663955; called by muse, mutect2, varscan2
- ZBTB21 | c.1905G>C p.L635= | Silent (SNP) | VAF 4/90 reads (4%) | catalogued as COSV100177403; called by muse, mutect2
- ZFYVE9 | c.3060C>T p.F1020= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99820883; called by muse, mutect2, varscan2
- ZNF248 | c.1074G>C p.G358= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV61998494; called by muse, mutect2, varscan2
- ZNF320 | c.225G>A p.Q75= | Silent (SNP) | VAF 11/182 reads (6%) | catalogued as COSV67088156, COSV67088416; called by muse, mutect2
- ZNF595 | c.27G>A p.V9= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV100227960; called by muse, mutect2, varscan2
- ZZEF1 | c.7068G>A p.L2356= | Silent (SNP) | VAF 9/137 reads (7%) | catalogued as COSV101068207, COSV67555981; called by muse, mutect2
- LGALS14 | c.16-668C>T | Intron (SNP) | VAF 9/106 reads (8%) | catalogued as rs779150542, COSV62372216; called by muse, mutect2
- MCMDC2 | chr8:66922489 T>A | 3'Flank (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- MIR99AHG | n.674G>A | RNA (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- MRAP | chr21:32314561 G>T | 3'Flank (SNP) | VAF 26/56 reads (46%) | catalogued as COSV100353373, COSV57937581; called by muse, mutect2, varscan2
- TMPRSS3 | chr21:42396080 C>T | 5'Flank (SNP) | VAF 13/30 reads (43%) | catalogued as COSV99368820; called by muse, mutect2, varscan2
